Somatic mutation profile of tumor specimen TCGA-4Z-AA7M-01A (aliquot TCGA-4Z-AA7M-01A-11D-A391-08) from TCGA case TCGA-4Z-AA7M, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 65.2 years (23,817 days).
Specimen TCGA-4Z-AA7M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5120fa79-20c1-4e07-b155-f11397db0c90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA7M-10A (Blood Derived Normal), aliquot TCGA-4Z-AA7M-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3f4e257-a077-43b3-bd30-588589139018

The open-access MAF lists 583 somatic variants for this specimen: 431 protein-altering or splice-affecting, 137 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 377, Silent 137, Nonsense Mutation 41, Frame Shift Del 6, Intron 5, Splice Site 4, RNA 4, 5'Flank 3, 5'UTR 2, Nonstop Mutation 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.4422G>A p.W1474* | Nonsense Mutation (SNP) | VAF 69/119 reads (58%) | catalogued as rs147622433; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7349G>A p.R2450Q (on ENST00000358273 / NM_001042492.3; = p.R2429Q on NM_000267.3) | Missense Mutation (SNP) | VAF 26/166 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs533110479, COSV62194514; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 18/29 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AAGAB | c.908G>C p.R303T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV56018083; called by muse, mutect2, varscan2
- ABCA13 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.901); catalogued as COSV70041415, COSV70043747; called by muse, mutect2, varscan2
- ABCB4 | c.1082G>C p.R361T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1385666584, COSV55940512, COSV99709876; called by muse, mutect2, varscan2
- ACOT7 | c.547C>T p.R183W (on ENST00000377855 / NM_181864.3; = p.R173W on NM_007274.4) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as rs746248748, COSV64115084; called by muse, mutect2, varscan2
- ADAM10 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.704); catalogued as COSV53054039; called by muse, mutect2, varscan2
- ADAM12 | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64112792; called by muse, mutect2, varscan2
- ADAMTSL4 | c.911C>G p.S304W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV55005348; called by muse, mutect2, varscan2
- ADGRG7 | c.1366C>G p.Q456E | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV56300233; called by muse, varscan2
- ADGRL3 | c.2995A>T p.I999F (on ENST00000506720 / NM_001322402.2; = p.I931F on NM_015236.6) | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV72231654; called by muse, mutect2, varscan2
- ADH7 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV52922667; called by muse, mutect2, varscan2
- AFAP1L2 | c.1862G>A p.R621K | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58417886; called by muse, mutect2, varscan2
- ALDH18A1 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV64663455; called by muse, mutect2, varscan2
- ALMS1 | c.10940C>G p.S3647* | Nonsense Mutation (SNP) | VAF 40/106 reads (38%) | catalogued as COSV100043016; called by muse, mutect2, varscan2
- ALPK2 | c.6420G>T p.Q2140H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.907); catalogued as COSV64496017; called by muse, mutect2, varscan2
- ANLN | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.395); catalogued as COSV56078757; called by muse, mutect2, varscan2
- ARHGAP21 | c.4708G>A p.E1570K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV57608678; called by muse, mutect2, varscan2
- ARHGAP32 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100088383; called by muse, mutect2
- ARHGAP45 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV57435093; called by muse, mutect2, varscan2
- ARMC5 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs755022816, COSV51659217; called by muse, mutect2, varscan2
- ARPC5 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54171386, COSV54172345; called by muse, mutect2, varscan2
- ASXL1 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1485128289, COSV60107738; called by muse, mutect2, varscan2
- ASXL1 | c.1232G>T p.R411L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60118199; called by muse, mutect2, varscan2
- AUTS2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs1229542823, COSV100717599, COSV61424631; called by muse, mutect2, varscan2
- BDP1 | c.6322G>C p.E2108Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.117); catalogued as COSV62433826; called by muse, mutect2, varscan2
- BEND3 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV64681999; called by muse, mutect2, varscan2
- BMP8A | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59033252; called by muse, mutect2
- BRAF | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as CM080111, COSV56330121, COSV56374895; called by muse, mutect2, varscan2
- BRD9 | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs761934433, COSV60245090; called by muse, mutect2, varscan2
- BRMS1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs541164374, COSV60819900; called by muse, mutect2, varscan2
- BTBD7 | c.1832C>T p.T611M | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58287867; called by muse, mutect2, varscan2
- C12orf65 | c.423G>C p.R141S | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV53516946, COSV53516986; called by muse, mutect2, varscan2
- C1QTNF2 | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); catalogued as rs1301588261, COSV67433218; called by muse, mutect2, varscan2
- CA9 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as rs760594473, COSV100999906, COSV65676345; called by muse, mutect2, varscan2
- CACNA1E | c.2804C>A p.S935* | Nonsense Mutation (SNP) | VAF 39/151 reads (26%) | catalogued as COSV100703941; called by muse, mutect2, varscan2
- CACNA1G | c.6713C>T p.P2238L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV61735728; called by muse, mutect2, varscan2
- CADM1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59020302; called by muse, mutect2, varscan2
- CALCRL | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV66476799; called by muse, mutect2, varscan2
- CARM1 | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV59002708; called by muse, mutect2, varscan2
- CAVIN1 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as COSV63812581; called by muse, mutect2, varscan2
- CBLL1 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs556313861, COSV56030253; called by muse, mutect2, varscan2
- CCDC18 | c.3313C>G p.Q1105E (on ENST00000343253 / NM_001306076.1; = p.Q1106E on NM_206886.4) | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as COSV58146688; called by muse, mutect2, varscan2
- CCDC66 | c.1027G>A p.D343N (on ENST00000394672 / NM_001353147.1; = p.D309N on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.755); catalogued as COSV58308115; called by muse, mutect2, varscan2
- CCM2 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51850710; called by muse, mutect2, varscan2
- CD2BP2 | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59769403, COSV59769604; called by muse, mutect2, varscan2
- CD2BP2 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as COSV59769613; called by muse, mutect2, varscan2
- CD93 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1418770351, COSV55664350, COSV55667994; called by muse, mutect2, varscan2
- CDIPT | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1035053208, COSV54889362; called by muse, mutect2, varscan2
- CEACAM6 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.691); catalogued as COSV52267025, COSV52268874, COSV52268928; called by muse, mutect2, varscan2
- CEP170 | c.3398C>G p.S1133C | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100317426; called by muse, mutect2, varscan2
- CFAP47 | c.1432C>G p.P478A | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52882486, COSV52890211; called by muse, mutect2, varscan2
- CFTR | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM024684, COSV50086021; called by muse, mutect2, varscan2
- CHCHD7 | c.223G>C p.E75Q (on ENST00000355315 / NM_001011671.3; = p.E87Q on NM_024300.4) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.079); catalogued as COSV58132791; called by muse, mutect2, varscan2
- CHD1 | c.1876C>G p.L626V | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52343871; called by muse, mutect2, varscan2
- CHD7 | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as COSV71115540; called by muse, varscan2
- CHMP7 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as COSV57533698; called by muse, mutect2, varscan2
- CHPT1 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1483032283; called by mutect2, varscan2
- CHRNE | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV53419498; called by muse, mutect2, varscan2
- CLCA2 | c.2599C>T p.R867* | Nonsense Mutation (SNP) | VAF 36/153 reads (24%) | catalogued as rs150119696; called by muse, mutect2, varscan2
- CLHC1 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs766514446, COSV68464871; called by muse, mutect2, varscan2
- CLMP | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV71650487; called by muse, mutect2, varscan2
- CNOT1 | c.5519C>G p.S1840* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99800646; called by muse, mutect2, varscan2
- CNOT1 | c.5355C>G p.F1785L | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV55321211; called by muse, mutect2, varscan2
- COL11A1 | c.4996G>A p.E1666K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62193655; called by muse, mutect2, varscan2
- COL12A1 | c.4166C>G p.S1389C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV59405060; called by muse, mutect2, varscan2
- COL19A1 | c.1610G>A p.G537E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59584084; called by muse, mutect2, varscan2
- COPB1 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV99999729; called by muse, mutect2, varscan2
- CPA6 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 97/139 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745811365, COSV52721197, COSV52740263; called by muse, mutect2, varscan2
- CPAMD8 | c.5521G>C p.E1841Q (on ENST00000651564; = p.E1794Q on NM_015692.5) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.765); catalogued as COSV50186315; called by muse, mutect2, varscan2
- CRLF1 | c.981G>C p.W327C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62260943; called by muse, mutect2, varscan2
- CRLF1 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs892215986, COSV100679014; called by muse, mutect2
- CRLF3 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV60836967, COSV99048251; called by muse, mutect2, varscan2
- CSDE1 | c.415C>G p.L139V (on ENST00000358528 / NM_001007553.3; = p.L108V on NM_007158.6) | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54756801; called by muse, mutect2, varscan2
- CSMD1 | c.9401C>A p.A3134D (on ENST00000520002; = p.A3133D on NM_033225.6) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59368908; called by muse, mutect2, varscan2
- CTAGE1 | c.1259A>C p.K420T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV66944403; called by muse, mutect2, varscan2
- CTNNA2 | c.2372T>A p.I791N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58173335; called by muse, mutect2, varscan2
- CWC22 | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as COSV55431279; called by muse, mutect2, varscan2
- CYP11B1 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438989835, COSV52825855, COSV52829716; called by muse, mutect2, varscan2
- CYP4A11 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100152510, COSV60225151; called by muse, mutect2, varscan2
- CYP7A1 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753399056, COSV56965283; called by muse, mutect2, varscan2
- CYRIB | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.474); catalogued as COSV67832466; called by muse, varscan2
- DCLK3 | c.288del p.R97Gfs*82 | Frame Shift Del (DEL) | VAF 55/180 reads (31%) | catalogued as rs1308457131, COSV69364944; called by mutect2, pindel, varscan2
- DCUN1D1 | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV53045819; called by muse, mutect2, varscan2
- DDHD1 | c.2017G>A p.D673N (on ENST00000323669; = p.D870N on NM_030637.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV60361830; called by muse, mutect2, varscan2
- DDX20 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63781032; called by muse, mutect2, varscan2
- DEDD | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63502590; called by muse, mutect2, varscan2
- DEFB112 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.023); catalogued as COSV59182448, COSV59182890; called by muse, mutect2, varscan2
- DENND2C | c.1327G>A p.E443K (on ENST00000393274 / NM_001256404.2; = p.E386K on NM_198459.4) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV67923603; called by muse, mutect2, varscan2
- DHTKD1 | c.2360C>T p.T787I | Missense Mutation (SNP) | VAF 79/149 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1368623517, COSV53806165; called by muse, mutect2, varscan2
- DLL4 | c.1745C>A p.A582D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV51069110; called by muse, mutect2, varscan2
- DNAJC6 | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV99675253; called by muse, mutect2
- DNLZ | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52518250; called by muse, mutect2, varscan2
- DNPH1 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs768465761, COSV52733053; called by muse, mutect2, varscan2
- DOCK6 | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV52949509; called by muse, mutect2, varscan2
- DOK2 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs757494381, COSV99374639; called by muse, mutect2, varscan2
- DPP10 | c.938G>T p.S313I | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV59715091; called by muse, mutect2, varscan2
- DRC1 | c.1105C>G p.L369V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56534496; called by muse, mutect2, varscan2
- DRC7 | c.1014C>G p.I338M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs200287537, COSV61053684; called by muse, mutect2, varscan2
- EGLN1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs1384033809, COSV100791306; called by muse, mutect2
- EIF3L | c.314G>C p.R105T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV67739998; called by muse, varscan2
- ELK4 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV56985984; called by muse, mutect2, varscan2
- EMILIN2 | c.2122C>A p.H708N | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54426610; called by muse, mutect2, varscan2
- EP400 | c.2429G>A p.R810H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760596309, COSV57771141; called by muse, mutect2, varscan2
- EPB41L4A | c.1853C>G p.S618* | Nonsense Mutation (SNP) | VAF 19/33 reads (58%) | catalogued as COSV99813687; called by muse, mutect2, varscan2
- EPHX3 | c.307C>A p.L103M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55656418, COSV99691517; called by muse, mutect2, varscan2
- ERBIN | c.1745C>G p.S582C | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV52324675; called by muse, mutect2, varscan2
- ERICH3 | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | catalogued as COSV58598332, COSV58614939; called by muse, mutect2, varscan2
- FAM13A | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1167196980, COSV52011074; called by muse, mutect2, varscan2
- FAM151B | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56474848; called by muse, mutect2, varscan2
- FAM184A | c.803G>C p.R268T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58857687; called by muse, mutect2, varscan2
- FAM216B | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs747822576, COSV58271194; called by muse, mutect2, varscan2
- FBXO30 | c.614G>C p.R205T | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as COSV52792098; called by muse, mutect2, varscan2
- FBXW4 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58708677; called by muse, mutect2, varscan2
- FLG2 | c.3854C>G p.S1285* | Nonsense Mutation (SNP) | VAF 51/355 reads (14%) | catalogued as COSV101166024; called by muse, mutect2, varscan2
- FLT1 | c.1427C>G p.S476C | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV56721303, COSV56738867; called by muse, mutect2, varscan2
- FLVCR1 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63134434; called by muse, mutect2, varscan2
- FOXE1 | c.426C>A p.F142L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64300877; called by muse, mutect2, varscan2
- FOXN3 | c.774G>C p.M258I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV54314865; called by mutect2, varscan2
- FOXR1 | c.611+1G>A p.X204_splice | Splice Site (SNP) | VAF 14/60 reads (23%) | catalogued as rs201483514, COSV57653497; called by muse, mutect2, varscan2
- FREM2 | c.6733G>C p.D2245H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV54848515, COSV99748709; called by muse, mutect2, varscan2
- FRY | c.4300G>A p.E1434K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66577162; called by muse, mutect2, varscan2
- FTHL17 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV63267670; called by muse, mutect2, varscan2
- FUBP3 | c.146C>G p.S49* | Nonsense Mutation (SNP) | VAF 48/101 reads (48%) | catalogued as COSV100156218, COSV60512985; called by muse, mutect2, varscan2
- FUT7 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs761990061, COSV55805332; called by muse, varscan2
- GBF1 | c.3148G>C p.E1050Q (on ENST00000369983 / NM_001377137.1; = p.E1049Q on NM_004193.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV64148198; called by muse, mutect2
- GCC2 | c.2944G>C p.D982H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59179255; called by muse, varscan2
- GEMIN2 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51629355, COSV99158196; called by muse, varscan2
- GGT5 | c.1534G>C p.D512H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1340738250; called by mutect2, varscan2
- GLYATL2 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV54851110; called by muse, mutect2, varscan2
- GNMT | c.585C>G p.I195M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV99769865; called by muse, mutect2, varscan2
- GPR108 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV51186697; called by muse, varscan2
- GPR108 | c.402G>C p.Q134H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.783); catalogued as COSV51186726; called by muse, varscan2
- GRIK3 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as rs773388016, COSV66145236; called by muse, mutect2, varscan2
- GRK6 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs371241210, COSV100586966; called by muse, mutect2, varscan2
- H2AC11 | c.85G>C p.G29R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.627); catalogued as COSV60362609; called by muse, mutect2, varscan2
- HACL1 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 90/182 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV58256169; called by muse, mutect2, varscan2
- HAUS6 | c.1234C>G p.P412A | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV65840628; called by muse, mutect2, varscan2
- HGSNAT | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52818526; called by muse, mutect2, varscan2
- HIVEP2 | c.2336C>T p.S779L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV50041906; called by muse, mutect2, varscan2
- HIVEP2 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV50042058; called by muse, mutect2, varscan2
- HIVEP2 | c.672C>G p.F224L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50029595, COSV50042184; called by muse, mutect2, varscan2
- HMBOX1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV55071260; called by muse, mutect2, varscan2
- HMCN1 | c.6917G>C p.R2306P | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV54894302; called by muse, mutect2, varscan2
- HMOX1 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as COSV53340992; called by muse, mutect2, varscan2
- HNRNPAB | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.565); catalogued as COSV57425821; called by muse, mutect2, varscan2
- HOATZ | c.400-1G>A p.X134_splice (on ENST00000375618 / NM_001100388.1; = p.X161_splice on NM_207430.2) | Splice Site (SNP) | VAF 27/58 reads (47%) | catalogued as rs1282255316, COSV60442255; called by muse, mutect2, varscan2
- HRNR | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV64255284, COSV64261832; called by muse, mutect2, varscan2
- HSP90B1 | c.1075T>C p.Y359H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354079125, COSV55357409; called by muse, mutect2, varscan2
- HSPA4 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.388); catalogued as COSV59183372; called by muse, mutect2, varscan2
- HSPA4L | c.2306C>G p.S769* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99613278; called by muse, mutect2, varscan2
- HSPA9 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.387); catalogued as rs1283153643, COSV51865897; called by muse, mutect2, varscan2
- HTR7 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs868767846, COSV53290161; called by muse, mutect2, varscan2
- HTT | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.427); catalogued as COSV61867641; called by muse, mutect2, varscan2
- IFI44L | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV60729033; called by muse, mutect2, varscan2
- IGFL3 | c.24G>A p.L8= | Splice Region (SNP) | VAF 17/62 reads (27%) | catalogued as COSV58243263; called by muse, mutect2, varscan2
- IGFL4 | c.168G>C p.L56F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV66619036; called by muse, mutect2, varscan2
- IGSF10 | c.5611C>T p.Q1871* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99183645; called by muse, mutect2
- INPPL1 | c.2629G>C p.E877Q | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV53358545; called by muse, mutect2, varscan2
- INPPL1 | c.2797G>C p.E933Q | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV53358554; called by muse, mutect2, varscan2
- INSRR | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100693433, COSV62327915; called by muse, mutect2, varscan2
- INTS7 | c.2768G>T p.R923I | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV65345084; called by muse, mutect2, varscan2
- IPCEF1 | c.1188G>A p.M396I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV54549829; called by muse, mutect2, varscan2
- ITGA9 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs199626430, COSV53250416; called by muse, mutect2, varscan2
- ITGAL | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357007860, COSV63323742; called by muse, mutect2, varscan2
- ITIH4 | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV56577608; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2299G>C p.E767Q | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs952406814, COSV58026506; called by muse, mutect2, varscan2
- KCMF1 | c.419G>C p.R140T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV69054574; called by muse, mutect2, varscan2
- KCNF1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.052); catalogued as rs773536391, COSV54462309, COSV54464047; called by muse, mutect2, varscan2
- KCNMB4 | c.198C>G p.F66L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.808); catalogued as COSV50692759; called by muse, mutect2, varscan2
- KCNRG | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.902); catalogued as COSV53948800, COSV53949445; called by muse, varscan2
- KCNRG | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53951217; called by muse, varscan2
- KIF20B | c.3803C>T p.S1268F (on ENST00000371728 / NM_001284259.2; = p.S1228F on NM_016195.4) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as COSV53313875; called by muse, mutect2, varscan2
- KIF3B | c.1917G>C p.L639F | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV65229016; called by muse, mutect2, varscan2
- KIF3B | c.2233G>C p.V745L | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV65229020; called by muse, mutect2, varscan2
- KIF5A | c.2900C>G p.S967* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99673226; called by muse, mutect2, varscan2
- KIFAP3 | c.2155G>C p.D719H | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV63031440; called by muse, mutect2, varscan2
- KMT2E | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.175); catalogued as COSV57578347, COSV99995798; called by muse, mutect2, varscan2
- KPNB1 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV51599855; called by muse, varscan2
- KRT5 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV52862892; called by muse, mutect2, varscan2
- L3MBTL3 | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV62386394, COSV62388317; called by muse, mutect2, varscan2
- LECT2 | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50846752, COSV50847575; called by muse, mutect2, varscan2
- LMBRD2 | c.838C>G p.Q280E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.524); catalogued as COSV56952061; called by muse, mutect2, varscan2
- LRP1 | c.4770G>C p.Q1590H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV54521785; called by muse, mutect2, varscan2
- LRP1B | c.9716G>C p.R3239P | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67215289, COSV67262017; called by muse, mutect2, varscan2
- LRRC49 | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV53014413; called by muse, mutect2, varscan2
- LYSMD1 | c.359C>G p.S120* | Nonsense Mutation (SNP) | VAF 40/118 reads (34%) | catalogued as COSV100925222; called by muse, mutect2, varscan2
- MAGEC1 | c.1070del p.S357Ffs*30 | Frame Shift Del (DEL) | VAF 28/105 reads (27%) | catalogued as COSV53579443, COSV53582109; called by mutect2, pindel, varscan2
- MANBA | c.2392G>T p.E798* (on ENST00000642252; = p.E752* on NM_005908.4) | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99898910; called by muse, mutect2, varscan2
- MAP1A | c.4167G>C p.Q1389H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.346); catalogued as COSV55811741; called by muse, mutect2, varscan2
- MAP1A | c.4255G>C p.D1419H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.561); catalogued as COSV55811748, COSV55813184; called by muse, mutect2, varscan2
- MAP1B | c.3380C>A p.S1127Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV57104599; called by muse, mutect2, varscan2
- MAP3K1 | c.3535G>A p.E1179K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV68122442, COSV68126441; called by muse, mutect2, varscan2
- MARCO | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59057452; called by muse, mutect2, varscan2
- MCUB | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1388605074, COSV54461731; called by muse, mutect2
- MECP2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 89/124 reads (72%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.484); catalogued as COSV57656222; called by muse, mutect2, varscan2
- MEGF8 | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV52097881; called by muse, mutect2, varscan2
- MFSD14A | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs1271978585, COSV64515159; called by muse, mutect2, varscan2
- MGA | c.5911G>A p.E1971K (on ENST00000219905 / NM_001164273.1; = p.E1762K on NM_001080541.2) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); catalogued as COSV54960996; called by muse, mutect2, varscan2
- MLEC | c.511A>G p.M171V | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57330194; called by muse, mutect2
- MMS19 | c.3016G>A p.D1006N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59137023; called by muse, mutect2, varscan2
- MRPL20 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs775815488, COSV61224529; called by muse, mutect2, varscan2
- MRPL3 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as COSV53915805; called by muse, mutect2, varscan2
- MSTO1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV55473106; called by muse, mutect2, varscan2
- MUC17 | c.8782A>G p.T2928A | Missense Mutation (SNP) | VAF 75/295 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV60300082; called by muse, mutect2, varscan2
- MUC2 | c.2929C>T p.R977C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); catalogued as rs773009382; called by muse, mutect2, varscan2
- MVB12B | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 86/145 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63260442; called by muse, mutect2, varscan2
- MYH13 | c.864C>G p.F288L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52839528; called by muse, mutect2, varscan2
- MYH13 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.078); catalogued as COSV52839547, COSV52844665; called by muse, mutect2, varscan2
- MYOM2 | c.70C>G p.Q24E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as COSV50755352; called by muse, mutect2, varscan2
- MYOZ2 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61085899; called by muse, mutect2, varscan2
- NAP1L3 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV59077245; called by muse, mutect2, varscan2
- NAV3 | c.5165C>T p.S1722F | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV57105338; called by muse, mutect2, varscan2
- NCAPH2 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100238292; called by muse, mutect2, varscan2
- NCOA6 | c.1737G>A p.M579I | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV62866956; called by muse, mutect2, varscan2
- NCOR1 | c.5521G>C p.E1841Q | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV51990680; called by muse, mutect2, varscan2
- NDUFB2 | c.317G>C p.*106Sext*30 | Nonstop Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV99199981; called by muse, mutect2, varscan2
- NDUFB4 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as rs929208002, COSV51742797; called by muse, mutect2, varscan2
- NET1 | c.934C>T p.R312* (on ENST00000355029 / NM_001047160.3; = p.R258* on NM_005863.5) | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as rs1263085638, COSV100742330; called by muse, mutect2, varscan2
- NFXL1 | c.1249_1270del p.S417Afs*78 | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | catalogued as COSV61200324; called by mutect2, pindel
- NKAIN4 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100941639; called by muse, mutect2, varscan2
- NLN | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV66766948; called by muse, mutect2, varscan2
- NLRP3 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as rs746159202, COSV100275560, COSV60223782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOLC1 | c.1528A>T p.K510* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100893703; called by muse, mutect2, varscan2
- NOP14 | c.2459C>G p.S820* | Nonsense Mutation (SNP) | VAF 34/208 reads (16%) | catalogued as COSV100054844; called by muse, mutect2, varscan2
- NRXN2 | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as rs770105914, COSV99634989; called by muse, mutect2, varscan2
- NSUN7 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV57273810; called by muse, mutect2, varscan2
- NUCB1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.978); catalogued as COSV54385289; called by muse, mutect2, varscan2
- NUP210 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV54409162, COSV54412156; called by muse, mutect2, varscan2
- NUP43 | c.81G>C p.Q27H | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV61189099, COSV61191024; called by muse, mutect2, varscan2
- OGA | c.1868G>C p.G623A | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV63382975; called by muse, mutect2, varscan2
- OR10A4 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.168); catalogued as COSV65842364; called by muse, mutect2, varscan2
- OR10J3 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV59955382; called by muse, varscan2
- OR10J3 | c.410T>C p.M137T | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV59955387; called by muse, varscan2
- OR10Z1 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV63524679; called by muse, mutect2, varscan2
- OR1S2 | c.570C>G p.F190L | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56920329; called by muse, mutect2, varscan2
- OR2B11 | c.421C>G p.H141D | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV59511108; called by muse, mutect2, varscan2
- OR4K17 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 28/145 reads (19%) | catalogued as COSV100210736; called by muse, mutect2, varscan2
- OSBPL3 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV57661231; called by muse, mutect2, varscan2
- OSBPL8 | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV53887978; called by muse, mutect2, varscan2
- OTUD7B | c.1935G>C p.Q645H | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64917506; called by muse, mutect2, varscan2
- PA2G4 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV57260694; called by muse, varscan2
- PABPC4 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV65724170; called by muse, mutect2, varscan2
- PACC1 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1335778775, COSV54789259; called by muse, mutect2, varscan2
- PC | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV63082235; called by muse, mutect2, varscan2
- PCDHA13 | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.171); catalogued as COSV56485794, COSV56496336, COSV99167324; called by muse, mutect2, varscan2
- PCDHB14 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53390615; called by muse, mutect2, varscan2
- PCDHB16 | c.806T>C p.L269S | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as rs1554282132, COSV53369074; called by muse, mutect2, varscan2
- PCDHGA1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.038); catalogued as COSV65298717; called by muse, mutect2, varscan2
- PDGFD | c.177A>T p.K59N | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV56390525; called by muse, mutect2, varscan2
- PDIA3 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.555); catalogued as rs553813975, COSV55857885; called by muse, mutect2, varscan2
- PDILT | c.444G>C p.L148F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1295249670, COSV56702447; called by muse, mutect2, varscan2
- PDPK1 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV51914246; called by muse, mutect2, varscan2
- PHF20 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as COSV59188276; called by muse, mutect2, varscan2
- PKN2 | c.1772C>G p.S591C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV60134604; called by muse, mutect2, varscan2
- PLAAT1 | c.727C>G p.R243G (on ENST00000650797; = p.R138G on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as rs151296838, COSV53232881, COSV53234504; called by muse, mutect2, varscan2
- PLCL2 | c.2815-1G>A p.X939_splice (on ENST00000615277 / NM_001144382.2; = p.X813_splice on NM_015184.5) | Splice Site (SNP) | VAF 112/231 reads (48%) | catalogued as COSV67622101, COSV67624547; called by muse, mutect2, varscan2
- PLEKHG1 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.627); catalogued as COSV62050306; called by muse, mutect2, varscan2
- PLK4 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.423); catalogued as COSV54638902; called by muse, mutect2, varscan2
- PLPBP | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV60240244; called by muse, mutect2, varscan2
- POU6F2 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.001); catalogued as COSV68880570; called by muse, mutect2, varscan2
- PPFIA2 | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as rs993946124, COSV61049287; called by muse, mutect2, varscan2
- PPL | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746735184, COSV62049954; called by muse, mutect2, varscan2
- PPP1R10 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV64740217; called by muse, mutect2, varscan2
- PPP1R15A | c.1445G>C p.W482S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as rs759645779, COSV52340085; called by muse, mutect2, varscan2
- PPP1R3C | c.86G>A p.C29Y | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as rs764533207, COSV53289277; called by muse, mutect2, varscan2
- PPP2R2C | c.1245C>G p.I415M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59446962; called by muse, mutect2, varscan2
- PPRC1 | c.4912G>A p.D1638N | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV53387810; called by muse, mutect2, varscan2
- PRAMEF1 | c.649T>C p.W217R | Missense Mutation (SNP) | VAF 101/452 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.461); catalogued as COSV60016550; called by muse, mutect2, varscan2
- PROSER1 | c.2820G>C p.Q940H | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV61489132; called by muse, varscan2
- PRPF4B | c.2761C>T p.Q921* | Nonsense Mutation (SNP) | VAF 26/125 reads (21%) | catalogued as COSV100528279; called by muse, mutect2, varscan2
- PSME4 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV66367049; called by muse, mutect2, varscan2
- PTPN11 | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV61011994; called by muse, mutect2, varscan2
- PTPN4 | c.2661G>A p.M887I | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV55300598; called by muse, mutect2, varscan2
- PTPRT | c.3319G>A p.E1107K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as rs1453093376, COSV61968955; called by muse, mutect2, varscan2
- PUM3 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.073); catalogued as COSV67397241; called by muse, mutect2, varscan2
- PVR | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.716); catalogued as COSV51824449; called by muse, mutect2, varscan2
- PYGB | c.1400C>A p.S467* | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | catalogued as COSV99405258; called by muse, mutect2, varscan2
- QRICH1 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62617304; called by muse, mutect2, varscan2
- RAI14 | c.1535C>G p.S512* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99463880; called by muse, mutect2, varscan2
- RBMXL1 | c.604C>G p.R202G | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as COSV53098739, COSV53104678; called by muse, mutect2, varscan2
- RFC3 | c.890C>A p.S297* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV101197837; called by muse, mutect2, varscan2
- RNASEL | c.1260C>G p.F420L | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.022); catalogued as COSV104423149, COSV62377739; called by muse, mutect2, varscan2
- RNF123 | c.3788C>G p.S1263C | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57539807; called by muse, mutect2, varscan2
- ROPN1 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 64/148 reads (43%) | catalogued as COSV99481493; called by muse, mutect2, varscan2
- RP1L1 | c.2842C>G p.L948V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66751584, COSV66758999; called by muse, mutect2, varscan2
- RPS6KA2 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99691489; called by muse, mutect2
- RSC1A1 | c.1430C>A p.S477* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100197761; called by muse, mutect2, varscan2
- RXFP1 | c.1757-2A>G p.X586_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV57054971; called by muse, mutect2, varscan2
- RYR1 | c.12028G>C p.E4010Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as CM152884, COSV100615442, COSV62090314, COSV62107399; called by muse, mutect2, varscan2
- RYR3 | c.1711G>C p.E571Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66804967; called by muse, mutect2, varscan2
- SACS | c.3172A>T p.I1058L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV66545609; called by muse, mutect2, varscan2
- SAFB | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.112); catalogued as rs756589107, COSV52651292, COSV52652226, COSV52653358; called by muse, mutect2, varscan2
- SBF1 | c.5024C>G p.A1675G | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62369939; called by muse, mutect2, varscan2
- SCN9A | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1352403629, COSV100313448; called by muse, mutect2
- SEC14L1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.41); catalogued as COSV66724683; called by muse, mutect2, varscan2
- SEC61A2 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 70/112 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53654397; called by muse, varscan2
- SEMA7A | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs771064266, COSV56091988; called by muse, mutect2, varscan2
- SEPTIN1 | c.1155A>C p.E385D (on ENST00000321367; = p.E338D on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as COSV58443313; called by muse, mutect2, varscan2
- SERPINA3 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs971314943, COSV67586904; called by muse, mutect2
- SERPINB4 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100345837, COSV61984790; called by muse, mutect2, varscan2
- SHANK3 | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1232748977, COSV53190170; called by muse, mutect2, varscan2
- SHF | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV52052056; called by muse, mutect2
- SIGLEC12 | c.809C>A p.A270D (on ENST00000291707 / NM_053003.4; = p.A152D on NM_033329.2) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.409); catalogued as COSV52464233; called by muse, mutect2, varscan2
- SKP1 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV60435666, COSV60436065; called by muse, mutect2, varscan2
- SLC20A1 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0.285); catalogued as COSV55612737; called by muse, mutect2, varscan2
- SLC22A12 | c.421T>C p.S141P | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as rs1454726138, COSV60573676; called by muse, mutect2, varscan2
- SLC25A13 | c.1881C>G p.I627M | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV55712290; called by muse, mutect2, varscan2
- SLC25A20 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59804488; called by muse, mutect2, varscan2
- SLC27A2 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV51061790; called by muse, mutect2, varscan2
- SLC35G3 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 32/427 reads (7%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.556); catalogued as COSV52012401; called by muse, mutect2
- SLC8A1 | c.813G>C p.Q271H | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.062); catalogued as COSV60493351; called by muse, mutect2, varscan2
- SLFN5 | c.117G>C p.Q39H | Missense Mutation (SNP) | VAF 93/135 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV55482918; called by muse, mutect2, varscan2
- SMARCC2 | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs1329146261, COSV57223448; called by muse, mutect2, varscan2
- SMG8 | c.2414G>C p.R805T | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV56284609, COSV56285867; called by muse, mutect2, varscan2
- SNTA1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs891869271, COSV99458820; called by muse, mutect2
- SOCS6 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV67546995; called by muse, mutect2, varscan2
- SON | c.5528C>G p.S1843C | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51668196; called by muse, mutect2, varscan2
- SORCS1 | c.1020T>A p.D340E | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.134); catalogued as COSV53896035; called by muse, mutect2, varscan2
- SOX6 | c.1160C>T p.S387L (on ENST00000528429 / NM_001145819.2; = p.S346L on NM_017508.3) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV57055159; called by muse, mutect2, varscan2
- SPAST | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as rs768241184, CM000430, CM107565, COSV59512678, COSV59514377; called by muse, varscan2
- SPAST | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs750360074, COSV59516685; called by muse, varscan2
- SPATA2 | c.816G>C p.L272F | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV56867933; called by muse, mutect2, varscan2
- SPATA5 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1560780127, COSV56782397; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPDYE5 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.143); catalogued as COSV71596458; called by muse, mutect2, varscan2
- SPEF2 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV56799781, COSV99214211; called by muse, mutect2, varscan2
- SPEF2 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.214); catalogued as COSV61552532; called by muse, mutect2, varscan2
- SPEN | c.7013C>T p.S2338L | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.058); catalogued as rs1271298950, COSV65366413; called by muse, mutect2, varscan2
- SPICE1 | c.2218G>C p.E740Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55623922; called by muse, mutect2, varscan2
- SPTBN4 | c.7510G>A p.E2504K | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV52542585; called by muse, mutect2, varscan2
- SPTBN5 | c.8995C>T p.Q2999* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs906137260, COSV100311811; called by muse, mutect2, varscan2
- SQLE | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99772453; called by muse, mutect2, varscan2
- SRMS | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV53922672, COSV99421476; called by muse, mutect2, varscan2
- STAT4 | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV61831739; called by muse, mutect2, varscan2
- STK31 | c.174C>G p.I58M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as COSV63455678, COSV63458747; called by muse, mutect2, varscan2
- SULF1 | c.2538G>C p.K846N | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV52690562; called by muse, mutect2
- SYNE1 | c.18031C>G p.L6011V (on ENST00000367255 / NM_182961.4; = p.L5940V on NM_033071.3) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV55072529; called by muse, mutect2, varscan2
- SYNGR2 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs774750671, COSV56745639; called by muse, mutect2, varscan2
- SYNJ2 | c.4384G>A p.E1462K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.024); catalogued as COSV100840244, COSV62899941; called by muse, mutect2, varscan2
- TAF1C | c.2575C>T p.Q859* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as rs748297838, COSV100499703; called by muse, mutect2, varscan2
- TAF1C | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs775914678, COSV58988661; called by muse, mutect2, varscan2
- TAS1R3 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs144635443, COSV100229675; called by muse, mutect2
- TAS2R20 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV67861540; called by muse, mutect2, varscan2
- TDRD3 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV52162064; called by muse, mutect2, varscan2
- TDRD6 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as rs768589583, COSV60175073; called by muse, mutect2, varscan2
- TDRD9 | c.1770A>C p.E590D | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV59153498; called by muse, varscan2
- TDRD9 | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 24/38 reads (63%) | catalogued as rs753079540, COSV100175361; called by muse, varscan2
- TEC | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as COSV67406046; called by muse, mutect2, varscan2
- TECPR1 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65784800; called by muse, mutect2, varscan2
- TEX15 | c.751G>A p.E251K (on ENST00000256246; = p.E634K on NM_001350162.2) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.121); catalogued as rs1266939675, COSV56352041; called by muse, mutect2, varscan2
- TFAP2D | c.759G>C p.L253F | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50447165; called by muse, mutect2, varscan2
- THBS2 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.074); catalogued as COSV64681510; called by muse, mutect2, varscan2
- THY1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as COSV52455088; called by muse, mutect2, varscan2
- TIGD7 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0.188); catalogued as COSV51916765; called by muse, mutect2, varscan2
- TIGD7 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1175418875, COSV51915356, COSV51916772; called by muse, mutect2, varscan2
- TIGD7 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 106/178 reads (60%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.922); catalogued as COSV51916782, COSV51916861; called by muse, mutect2, varscan2
- TJP2 | c.1273G>C p.D425H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55272143; called by muse, mutect2, varscan2
- TK1 | c.315C>G p.I105M | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs143988750, COSV56746475; called by muse, mutect2, varscan2
- TM9SF4 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV54110526; called by muse, mutect2, varscan2
- TM9SF4 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV54107965, COSV54110547; called by muse, mutect2, varscan2
- TMC7 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58582225; called by muse, mutect2, varscan2
- TMPRSS15 | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs146494364, COSV53038195; called by muse, mutect2, varscan2
- TNFAIP3 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52801560; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1380754282, COSV100552599; called by muse, mutect2
- TNN | c.1630G>C p.E544Q | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53433437; called by muse, mutect2, varscan2
- TNRC18 | c.5435C>A p.S1812Y | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs1310126345, COSV68169377; called by muse, mutect2, varscan2
- TNXB | c.8779G>A p.G2927R (on ENST00000647633; = p.G2680R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs759066378, COSV64485348; called by muse, varscan2
- TOGARAM1 | c.2456C>G p.P819R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV63894336; called by muse, mutect2, varscan2
- TOGARAM1 | c.3054C>G p.I1018M | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as COSV63894343; called by muse, mutect2, varscan2
- TPR | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV55216542, COSV55219002; called by muse, mutect2, varscan2
- TRAF3IP2 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV60676920; called by muse, mutect2, varscan2
- TRAK1 | c.877G>C p.D293H (on ENST00000327628 / NM_001349247.2; = p.D235H on NM_014965.5) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58262926; called by muse, mutect2, varscan2
- TRIM15 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747055127, COSV64990248; called by muse, mutect2, varscan2
- TRIO | c.6853G>A p.E2285K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as rs776030839, COSV100702745, COSV59988650; called by muse, mutect2
- TRIOBP | c.6164G>A p.G2055E (on ENST00000644935 / NM_001039141.3; = p.G342E on NM_007032.5) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV100462350, COSV58526190; called by muse, mutect2, varscan2
- TRPC7 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as rs1411431588, COSV100725409, COSV61462273; called by muse, mutect2, varscan2
- TSPOAP1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV52115713; called by muse, mutect2, varscan2
- TSSK2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV52818415; called by muse, mutect2, varscan2
- TTBK2 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1314463632, COSV51173609; called by muse, mutect2, varscan2
- TTLL1 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56738827, COSV56740331; called by muse, mutect2, varscan2
- TXNDC16 | c.1965G>C p.Q655H | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as COSV55985210, COSV55986720; called by muse, mutect2, varscan2
- UBL4A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 94/132 reads (71%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs782359606, COSV54837142; called by muse, mutect2, varscan2
- UMPS | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99229169; called by muse, mutect2
- UQCRC1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52552755; called by muse, mutect2, varscan2
- USF3 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.197); catalogued as COSV57076278; called by muse, mutect2, varscan2
- USP40 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392397004, COSV52480049, COSV52482662; called by muse, mutect2, varscan2
- UVSSA | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV66230703; called by muse, mutect2, varscan2
- VIT | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV64898719; called by muse, mutect2, varscan2
- VWA8 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV55703201; called by muse, mutect2, varscan2
- WDFY3 | c.9334G>T p.E3112* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99884417; called by muse, mutect2, varscan2
- WDR24 | c.1591G>C p.E531Q (on ENST00000248142; = p.E401Q on NM_032259.4) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.413); catalogued as COSV50197116, COSV50202437; called by muse, mutect2, varscan2
- WDR48 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1246289904, COSV56533762; called by muse, mutect2, varscan2
- WIZ | c.5608G>A p.D1870N (on ENST00000673675 / NM_001371589.1; = p.D775N on NM_021241.3) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs761379329, COSV54611106; called by muse, mutect2, varscan2
- WIZ | c.5206G>T p.E1736* (on ENST00000673675 / NM_001371589.1; = p.E641* on NM_021241.3) | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as rs1198517862, COSV99653474; called by muse, varscan2
- WIZ | c.4289G>T p.G1430V (on ENST00000673675 / NM_001371589.1; = p.G335V on NM_021241.3) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV54611284; called by muse, varscan2
- WIZ | c.4249G>A p.E1417K (on ENST00000673675 / NM_001371589.1; = p.E322K on NM_021241.3) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV54611313; called by muse, varscan2
- WNK1 | c.2512C>G p.Q838E | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.15); catalogued as COSV60042781; called by muse, mutect2, varscan2
- XIRP2 | c.10108C>T p.Q3370* (on ENST00000628543; = p.Q3545* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as rs1013476725, COSV99745017; called by muse, mutect2, varscan2
- YTHDC1 | c.1302G>A p.M434I (on ENST00000344157 / NM_001031732.4; = p.M416I on NM_133370.4) | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV60010319, COSV60011697; called by muse, mutect2, varscan2
- ZADH2 | c.708G>C p.E236D | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV59269416; called by muse, mutect2, varscan2
- ZC3H6 | c.2396C>T p.S799F | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV59670007; called by muse, mutect2, varscan2
- ZFP57 | c.1507C>A p.Q503K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65306791; called by muse, mutect2, varscan2
- ZFP57 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV65306795; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2404C>A p.Q802K | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.874); catalogued as COSV58744228; called by muse, mutect2, varscan2
- ZNF112 | c.2390G>C p.R797T (on ENST00000337401 / NM_001083335.2; = p.R791T on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100495847, COSV61621726; called by muse, mutect2, varscan2
- ZNF197 | c.2660G>C p.R887T | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.25); catalogued as COSV56077277; called by muse, mutect2, varscan2
- ZNF292 | c.5662G>C p.E1888Q | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV60545218; called by muse, mutect2, varscan2
- ZNF304 | c.1829C>G p.T610S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.33); catalogued as COSV56584617, COSV56585987; called by muse, mutect2, varscan2
- ZNF366 | c.379C>G p.Q127E | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.024); catalogued as COSV59218325; called by muse, mutect2, varscan2
- ZNF436 | c.1371G>C p.R457S | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.199); catalogued as COSV58359241; called by muse, mutect2, varscan2
- ZNF57 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as COSV60984430; called by muse, mutect2, varscan2
- ZNF622 | c.194C>G p.S65W | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV58074983; called by muse, mutect2, varscan2
- ZNF638 | c.2167G>C p.E723Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV52494459; called by muse, mutect2, varscan2
- ZNF646 | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54926178; called by muse, mutect2, varscan2
- ZNF800 | c.384A>C p.E128D | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56179077; called by muse, mutect2, varscan2
- ZNF804A | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.025); catalogued as rs756277343, COSV56466349; called by muse, mutect2, varscan2
- ZNF804B | c.3757C>G p.P1253A | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV60814506; called by muse, mutect2, varscan2
- ZNF93 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.646); catalogued as COSV59377782; called by muse, mutect2, varscan2
- ZYG11B | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs1270363831, COSV53756323; called by muse, mutect2, varscan2
- GAP43 | c.559del p.A187Lfs*23 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | called by pindel, varscan2
- IGHV1OR21-1 | c.15G>C p.W5C | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIR2DL4 | c.626C>T p.A209V (on ENST00000396284; = p.A170V on NM_001080770.2) | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KMT2D | c.16419dup p.N5474* | Frame Shift Ins (INS) | VAF 36/118 reads (31%) | called by mutect2, pindel, varscan2
- KMT2D | c.10716_10740del p.S3572Rfs*78 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- MAP3K12 | c.1605del p.S536Hfs*45 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- POLR2A | c.3562G>A p.E1188K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PRAMEF18 | c.214A>T p.T72S | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- TMEM236 | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 40/439 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.387); called by muse, mutect2
- TTC23L | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF98 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ABRAXAS2 | c.30C>T p.F10= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as rs762512173, COSV53718192; called by muse, mutect2, varscan2
- AC023055.1 | c.1149C>G p.L383= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV60244242; called by muse, mutect2, varscan2
- ACBD4 | c.579C>T p.S193= (on ENST00000376955 / NM_001378111.1; = p.R197W on NM_024722.4) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs546766187, COSV58850986; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4704C>T p.H1568= | Silent (SNP) | VAF 43/163 reads (26%) | catalogued as COSV54464205; called by muse, mutect2, varscan2
- ADRB1 | c.453C>T p.V151= | Silent (SNP) | VAF 49/102 reads (48%) | catalogued as COSV65168293; called by muse, mutect2, varscan2
- AHNAK2 | c.7248C>G p.L2416= | Silent (SNP) | VAF 83/177 reads (47%) | catalogued as rs756285959, COSV60926851; called by muse, mutect2, varscan2
- ALDH5A1 | c.573C>G p.L191= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs748553663, COSV62374401; called by muse, mutect2, varscan2
- ALMS1 | c.4419C>A p.S1473= | Silent (SNP) | VAF 62/143 reads (43%) | catalogued as COSV52519200, COSV52522643; called by muse, mutect2, varscan2
- ANK3 | c.3270G>A p.E1090= (on ENST00000280772 / NM_001320874.2; = p.E224= on NM_001149.3) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV55076518; called by muse, mutect2, varscan2
- ATP8B4 | c.1419C>G p.L473= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs761916821, COSV52719389, COSV52722315; called by muse, mutect2, varscan2
- BICC1 | c.792G>A p.V264= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV54066167; called by muse, mutect2, varscan2
- BIN3 | c.363C>G p.L121= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV52386169; called by muse, mutect2, varscan2
- BIRC2 | c.681C>A p.L227= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as COSV57162746; called by muse, mutect2, varscan2
- BSN | c.3255G>A p.R1085= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV56525436; called by muse, mutect2, varscan2
- BTAF1 | c.2631C>T p.I877= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV56438204; called by muse, mutect2, varscan2
- C16orf71 | c.612G>A p.R204= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV54794601; called by muse, varscan2
- C16orf71 | c.690G>T p.V230= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV54794609; called by muse, varscan2
- C19orf12 | c.189C>T p.A63= (on ENST00000392278 / NM_001031726.3; = p.A52= on NM_031448.6) | Silent (SNP) | VAF 49/335 reads (15%) | catalogued as rs775013096, COSV60365573; called by muse, mutect2, varscan2
- C20orf27 | c.180C>T p.I60= (on ENST00000379772 / NM_001258429.2; = p.I85= on NM_001039140.3) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV53925103; called by muse, mutect2, varscan2
- C6orf47 | c.303A>G p.Q101= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as COSV63264081; called by muse, mutect2, varscan2
- CACNA1A | c.216C>G p.L72= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV64209284; called by muse, mutect2, varscan2
- CD2BP2 | c.843G>C p.V281= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs748003924, COSV59768397, COSV59769597; called by muse, mutect2, varscan2
- CDH11 | c.1708C>T p.L570= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV51773591; called by muse, mutect2, varscan2
- CDH26 | c.222C>T p.L74= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV54844922; called by muse, mutect2, varscan2
- CDK4 | c.54G>A p.G18= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV56985752; called by muse, mutect2, varscan2
- CFL1 | c.99G>A p.K33= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV57381302; called by muse, mutect2, varscan2
- CHRNB2 | c.411C>G p.V137= | Silent (SNP) | VAF 85/205 reads (41%) | catalogued as COSV63809216; called by muse, mutect2, varscan2
- CLK1 | c.600T>C p.C200= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs773486012, COSV58435367; called by muse, mutect2, varscan2
- COG3 | c.435G>A p.L145= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV63074688; called by muse, mutect2, varscan2
- COQ10B | c.201C>T p.I67= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as COSV55837362; called by muse, mutect2, varscan2
- CORO1B | c.228G>A p.P76= | Silent (SNP) | VAF 35/56 reads (63%) | catalogued as rs752001928, COSV58171815; called by muse, mutect2, varscan2
- CPT1B | c.1497G>A p.T499= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs201226839, COSV56418495; called by muse, mutect2, varscan2
- CYCS | c.195G>A p.L65= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV59872900; called by muse, mutect2, varscan2
- DALRD3 | c.1137A>C p.P379= (on ENST00000341949 / NM_001009996.3; = p.P212= on NM_018114.5) | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV58246963; called by muse, mutect2, varscan2
- DCAF15 | c.498C>T p.L166= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1238906640, COSV99586863; called by muse, mutect2, varscan2
- DHTKD1 | c.2316C>T p.L772= | Silent (SNP) | VAF 41/76 reads (54%) | catalogued as COSV53806155; called by muse, mutect2, varscan2
- DMBT1 | c.5661C>A p.T1887= (on ENST00000338354 / NM_001377530.1; = p.T1130= on NM_004406.3) | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV57557081; called by muse, mutect2, varscan2
- DNAH5 | c.8913C>T p.F2971= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV54227090; called by muse, mutect2, varscan2
- DRC7 | c.2094G>A p.E698= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV61057391; called by muse, mutect2, varscan2
- DUSP7 | c.588G>C p.P196= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV56589608; called by muse, mutect2, varscan2
- FBXO42 | c.315G>A p.E105= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV65046653; called by muse, mutect2, varscan2
- FCRL5 | c.2328G>A p.L776= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as COSV62512484, COSV62518894; called by muse, mutect2, varscan2
- FER1L6 | c.1776C>T p.F592= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as COSV67552183; called by muse, mutect2, varscan2
- GAS2L2 | c.1152C>G p.P384= | Silent (SNP) | VAF 65/131 reads (50%) | catalogued as rs1555598996; called by muse, mutect2, varscan2
- GATB | c.51C>T p.F17= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as rs757217781, COSV56129302, COSV56131138; called by muse, mutect2, varscan2
- GCC2 | c.2973G>T p.V991= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV59179265; called by muse, mutect2, varscan2
- GIMAP1 | c.120G>A p.K40= | Silent (SNP) | VAF 64/142 reads (45%) | catalogued as COSV56189466; called by muse, mutect2, varscan2
- GLIS2 | c.567C>G p.V189= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV52109263; called by muse, mutect2, varscan2
- GNA11 | c.639G>C p.R213= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV50026415, COSV50037202; called by muse, mutect2, varscan2
- GPNMB | c.1635C>G p.L545= (on ENST00000381990 / NM_001005340.2; = p.L533= on NM_002510.3) | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as COSV51699665, COSV51700451; called by muse, mutect2, varscan2
- GRIN2A | c.81G>A p.A27= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV58032724; called by muse, mutect2
- GRIN2D | c.1176C>T p.L392= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs138100955; called by muse, mutect2, varscan2
- GRK5 | c.540G>A p.P180= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs199673866, COSV64867457; called by muse, mutect2, varscan2
- H3C10 | c.108C>T p.V36= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs757660879, COSV60798545; called by muse, mutect2, varscan2
- HERC2 | c.13560C>T p.L4520= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV55344421; called by muse, mutect2, varscan2
- HHIPL2 | c.546T>C p.P182= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV58567139; called by muse, mutect2, varscan2
- HIF3A | c.1824C>G p.L608= (on ENST00000377670 / NM_152795.4; = p.L539= on NM_022462.4) | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV52203224; called by muse, mutect2, varscan2
- HSPA8 | c.99G>A p.Q33= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV57085833; called by muse, mutect2, varscan2
- IGKV1D-17 | c.51C>T p.F17= | Silent (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- IGSF3 | c.3102G>A p.L1034= (on ENST00000369486 / NM_001007237.3; = p.L1054= on NM_001542.4) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV59596910; called by muse, varscan2
- ITFG2 | c.1035A>G p.Q345= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV57390729; called by muse, mutect2, varscan2
- KCNE1 | c.207G>A p.K69= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs762968991, COSV61607342; called by mutect2, varscan2
- KCNRG | c.291C>T p.L97= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV53951224; called by muse, mutect2, varscan2
- KIF13A | c.3607C>T p.L1203= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as rs1380823658, COSV52462571; called by muse, mutect2
- LPA | c.1083T>A p.T361= | Silent (SNP) | VAF 38/1004 reads (4%) | called by muse, mutect2
- LRP1 | c.8172C>T p.G2724= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as rs765902214, COSV54518484; called by muse, mutect2, varscan2
- LRRC10 | c.642G>A p.L214= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV64060652; called by muse, mutect2, varscan2
- LRRC14B | c.1188C>A p.L396= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs752227219, COSV57256374, COSV57257798; called by muse, mutect2, varscan2
- MAN1B1 | c.1050C>G p.L350= | Silent (SNP) | VAF 54/75 reads (72%) | catalogued as rs764043401, COSV65378446; called by muse, mutect2, varscan2
- MAP1B | c.168C>T p.I56= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99702635; called by muse, mutect2
- MAZ | c.708G>C p.L236= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV50717515; called by muse, mutect2, varscan2
- MCCC1 | c.159C>G p.L53= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV55606433, COSV55611202; called by muse, mutect2, varscan2
- MED19 | c.543G>A p.Q181= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs755413585, COSV54708763; called by muse, mutect2, varscan2
- MIDN | c.99C>T p.L33= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs778401653, COSV99960290; called by muse, varscan2
- MMRN1 | c.606C>T p.F202= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs773822697, COSV53333947, COSV99307231; called by muse, mutect2, varscan2
- MRPL20 | c.177G>A p.L59= | Silent (SNP) | VAF 83/222 reads (37%) | catalogued as COSV61224533; called by muse, mutect2, varscan2
- MYH14 | c.2319G>A p.L773= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV51828496; called by muse, mutect2, varscan2
- NCKAP5L | c.2913G>A p.L971= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1387457971, COSV60132635; called by muse, mutect2, varscan2
- NCOA3 | c.3873C>T p.S1291= (on ENST00000371998 / NM_181659.3; = p.S1287= on NM_006534.4) | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV59072312; called by muse, mutect2, varscan2
- NF1 | c.192T>C p.N64= | Silent (SNP) | VAF 20/188 reads (11%) | catalogued as COSV62216235; called by muse, mutect2, varscan2
- NRXN2 | c.4944C>A p.L1648= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV55461244; called by muse, mutect2, varscan2
- NRXN3 | c.2523T>C p.N841= (on ENST00000335750 / NM_001330195.2; = p.N468= on NM_004796.6) | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV59726183; called by muse, mutect2, varscan2
- NSMAF | c.2028G>A p.S676= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs187145398; called by muse, mutect2, varscan2
- NT5C1B | c.876G>A p.K292= (on ENST00000359846 / NM_001199086.2; = p.K232= on NM_033253.4) | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV58398355; called by muse, varscan2
- NWD1 | c.3499C>T p.L1167= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs950173956, COSV60339575, COSV60349352; called by muse, mutect2, varscan2
- OR4L1 | c.669C>G p.V223= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as COSV59850292, COSV59850994; called by muse, mutect2, varscan2
- OTUB1 | c.447G>A p.V149= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV55365938; called by muse, mutect2, varscan2
- PAM | c.2568G>A p.L856= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV57218333; called by muse, mutect2, varscan2
- PCDHAC2 | c.1161C>T p.L387= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs782426020, COSV53865019; called by muse, mutect2, varscan2
- PCDHB3 | c.1707C>T p.S569= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as rs782590457, COSV50614857; called by muse, mutect2, varscan2
- PCDHGA12 | c.1668C>T p.N556= | Silent (SNP) | VAF 41/189 reads (22%) | catalogued as rs775150918, COSV52764166; called by muse, mutect2, varscan2
- PHACTR3 | c.198C>T p.S66= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs747673720, COSV63032997; called by muse, mutect2, varscan2
- PLAAT5 | c.213C>G p.L71= | Silent (SNP) | VAF 56/233 reads (24%) | catalogued as COSV57138142; called by muse, mutect2, varscan2
- PLEKHG1 | c.9C>G p.L3= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV62050299; called by muse, mutect2, varscan2
- PPM1K | c.270C>T p.I90= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV55797473; called by muse, mutect2, varscan2
- PRTG | c.2031C>T p.L677= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs1367610940, COSV66840054; called by muse, mutect2, varscan2
- PTPRC | c.2031C>T p.N677= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs1408451047, COSV61419155; called by muse, mutect2, varscan2
- QARS1 | c.735C>A p.V245= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs1303947361, COSV60275947, COSV60276139; called by muse, mutect2, varscan2
- RAB43 | c.405C>T p.L135= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1312861169, COSV100167587; called by muse, mutect2, varscan2
- RAB4B | c.465C>T p.G155= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs150920149; called by muse, mutect2, varscan2
- RANGAP1 | c.501C>T p.T167= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs751689271, COSV62364458; called by muse, mutect2, varscan2
- RBCK1 | c.1185C>T p.F395= (on ENST00000356286 / NM_031229.4; = p.F353= on NM_006462.6) | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV62293125; called by muse, mutect2, varscan2
- RDH11 | c.291G>C p.R97= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as COSV67283233, COSV67283248; called by muse, mutect2, varscan2
- RGS22 | c.2184C>T p.Y728= | Silent (SNP) | VAF 111/140 reads (79%) | catalogued as rs772580442, COSV62661761, COSV62666291; called by muse, mutect2, varscan2
- RNF169 | c.18G>A p.P6= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100213467; called by muse, mutect2
- RUFY2 | c.1896C>G p.L632= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV56260734; called by muse, mutect2, varscan2
- RYR3 | c.9768C>A p.V3256= (on ENST00000389232; = p.V3257= on NM_001036.6) | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV66804971; called by muse, mutect2, varscan2
- SETD1A | c.426C>T p.F142= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV52691442; called by muse, varscan2
- SF3A2 | c.453C>T p.F151= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV55556459; called by muse, mutect2, varscan2
- SFTPA1 | c.639A>T p.R213= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV64867594; called by muse, mutect2, varscan2
- SLC4A9 | c.2478C>T p.I826= (on ENST00000507527 / NM_001258428.2; = p.I802= on NM_031467.3) | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV50206404, COSV99139214; called by muse, mutect2, varscan2
- SLIT1 | c.957C>T p.N319= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs759049531, COSV56582819, COSV56596846; called by muse, mutect2, varscan2
- STAP2 | c.213C>G p.L71= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV101654924, COSV74075493; called by muse, mutect2, varscan2
- SWSAP1 | c.492C>T p.A164= (on ENST00000312423; = p.A185= on NM_175871.4) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1385828814, COSV99710187; called by muse, mutect2
- TERT | c.1449C>T p.N483= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs761174773, COSV57205904, COSV57233607; ClinVar: likely benign; called by muse, mutect2, varscan2
- TIMELESS | c.1383G>C p.V461= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV57512135, COSV57514370; called by muse, mutect2, varscan2
- TMBIM6 | c.213G>C p.L71= | Silent (SNP) | VAF 41/225 reads (18%) | catalogued as COSV57280726; called by muse, mutect2, varscan2
- TMEM222 | c.258C>T p.F86= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as rs1553136111, COSV65026887; called by muse, mutect2, varscan2
- TMEM260 | c.1839G>A p.V613= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as COSV55101886; called by muse, mutect2, varscan2
- TNS1 | c.2955G>A p.L985= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1293995480, COSV99411239; called by muse, mutect2, varscan2
- TP53BP2 | c.2760G>A p.E920= (on ENST00000343537 / NM_001031685.3; = p.E791= on NM_005426.2) | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as rs938426809, COSV59071972; called by muse, mutect2, varscan2
- TREML2 | c.633G>C p.V211= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV72439232; called by muse, mutect2, varscan2
- TRPC4AP | c.1185C>G p.L395= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV52683420; called by muse, mutect2
- TSPO | c.273G>T p.L91= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100289845; called by muse, mutect2
- UPK1B | c.210C>T p.F70= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as COSV51768525; called by muse, mutect2, varscan2
- VCPIP1 | c.861G>A p.L287= | Silent (SNP) | VAF 11/154 reads (7%) | catalogued as COSV60049704; called by muse, mutect2
- VEGFC | c.96C>T p.F32= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1388348074, COSV54604692; called by muse, mutect2, varscan2
- VSTM1 | c.519C>T p.T173= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV58076328; called by muse, mutect2, varscan2
- WNK4 | c.3669C>T p.T1223= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs754710180, COSV55909028; called by muse, mutect2, varscan2
- WWP1 | c.714C>T p.A238= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs769578841, COSV99616756; called by muse, varscan2
- XKR6 | c.927C>T p.I309= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs753230172, COSV58659016; called by muse, mutect2, varscan2
- Z83844.2 | c.30C>T p.L10= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV60929430; called by muse, mutect2, varscan2
- ZBTB17 | c.2148C>G p.L716= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV65271405; called by muse, mutect2, varscan2
- ZMIZ1 | c.1083C>T p.S361= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs780853095, COSV57902120; called by muse, mutect2, varscan2
- ZNF257 | c.78G>A p.Q26= | Silent (SNP) | VAF 60/166 reads (36%) | catalogued as rs756254242, COSV71306617, COSV71306647; called by muse, mutect2, varscan2
- ZNF626 | c.1575A>G p.L525= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV74130546; called by muse, varscan2
- ZNF830 | c.348G>A p.A116= | Silent (SNP) | VAF 109/171 reads (64%) | catalogued as COSV58490823; called by muse, mutect2, varscan2
- BCL7A | c.561+19C>G | Intron (SNP) | VAF 52/95 reads (55%) | catalogued as COSV55850619; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24048223 G>C | 5'Flank (SNP) | VAF 23/37 reads (62%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93730637 G>C | 3'Flank (SNP) | VAF 38/91 reads (42%) | called by muse, mutect2, varscan2
- CNNM2 | c.1621+7268C>T | Intron (SNP) | VAF 60/153 reads (39%) | catalogued as COSV63996360; called by muse, mutect2, varscan2
- DCHS2 | n.2894A>C | RNA (SNP) | VAF 18/83 reads (22%) | catalogued as COSV59737142; called by muse, mutect2, varscan2
- DEK | c.-89C>G | 5'UTR (SNP) | VAF 5/11 reads (45%) | catalogued as rs1207072208, COSV99788993; called by muse, mutect2
- KIF1B | c.2115+6792C>G | Intron (SNP) | VAF 39/78 reads (50%) | catalogued as COSV55814165, COSV99822983; called by muse, mutect2, varscan2
- KIF1B | c.2115+7361C>T | Intron (SNP) | VAF 14/34 reads (41%) | catalogued as rs1334846250, COSV55813393; called by muse, mutect2, varscan2
- MFRP | chr11:119345509 G>C | 5'Flank (SNP) | VAF 14/31 reads (45%) | catalogued as COSV64129101; called by muse, mutect2, varscan2
- MIR518A2 | n.35C>G | RNA (SNP) | VAF 33/157 reads (21%) | called by muse, mutect2, varscan2
- PFKL | c.86-784C>G | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100827226, COSV62465578; called by muse, mutect2, varscan2
- POLR3D | chr8:22245004 C>T | 5'Flank (SNP) | VAF 14/76 reads (18%) | catalogued as rs1033115043; called by muse, mutect2, varscan2
- RPL17 | c.-99G>C | 5'UTR (SNP) | VAF 26/66 reads (39%) | catalogued as COSV100271733; called by muse, mutect2, varscan2
- SNORD116-7 | n.54G>A | RNA (SNP) | VAF 74/207 reads (36%) | catalogued as rs747308149; called by muse, mutect2, varscan2
- STAG3L4 | n.284C>T | RNA (SNP) | VAF 34/189 reads (18%) | called by muse, mutect2, varscan2
